Surgical pathology report (de-identified scan), TCGA case TCGA-76-6193, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6193-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-76-6193

FINAL DIAGNOSIS:

1. LEFT TEMPORAL BRAIN MASS (EXCISION): GLIOBLASTOMA, GRADE IV
OF IV
(WHO SCALE), SEE MICROSCOPIC DESCRIPTION, SEE NOTE

Comment:

The ki-67 proliferation index was performed on block 1B which was not representative of the most malignant portions of the tumor. Block 1c represents additional tissue that was subsequently submitted and is representative of the most malignant portions of this tumor and for which the diagnosis of glioblastoma is most appropriate.

.

[REDACTED]

Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Aperio

Ki67

Percent : 7%

3+ % : 2.3

2+ % : 1.1

1+ % : 3.6

0 % : 93

Cells counted : 9950

[page 2 of 3]
[REDACTED]

This test was performed by IHC in conjunction with the Aperio-computer assisted image analysis.

Due to significant artifactual counting of spurious cytoplasmic staining which was recorded by the Aperio as 1+ staining, a manual count of the highest areas of proliferation was performed. Ten 250 x 250 micron fields were counted and the percentage of labeled nuclei was determined. Almost 1,000 cells were counted. The manual proliferation index ranged from 4% to 10.6% with an overall average of 6.5% in good agreement with Aperio.

[REDACTED] Date Reported:

[REDACTED] Report Electronically Signed

Microscopic Description:

The tumor consists of a moderately pleomorphic and infiltrative proliferation of astrocytes. There is abundant endothelial proliferation and non-pseudo-palisading necrosis. There are scattered mitoses.

Frozen Section Diagnosis:

[REDACTED]
1. Left temporal mass: Glial neoplasm, final grading deferred to permanents

Clinical History and Diagnosis:

Left temporal brain tumor

Source of Specimen:

1: Left temporal mass

[page 3 of 3]
[REDACTED]

Gross Description:

[REDACTED]

1. Left temporal mass: Received fresh for frozen section in the specimen container labeled with patient's name and "#1 left temporal mass" is a 1.5 x 1 x 0.3 cm aggregate of tan-pink soft tissue. Touch prep is done. 50% of the specimen submitted for frozen section. The specimen is submitted as follows:

A. FSC.

B. remainder of the specimen

Histology Laboratory

H&E

Part 1: Left temporal mass

KI 67 (Aperio)

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED] Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 88034a5e-8a6a-4a92-b6b1-42ab7a421b7d (TCGA-76-6193.1EE55ECB-8DE5-4A21-9FA0-BABCB2D07212.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).